Somatic mutation profile of tumor specimen MMRF_2166_1_BM_CD138pos (aliquot MMRF_2166_1_BM_CD138pos_T1_KHS5U_L08849) from MMRF case MMRF_2166, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 88.1 years (32,196 days).
Specimen MMRF_2166_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf142c53-13e9-4926-b911-1dc35e070d10.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2166_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2166_1_PB_Whole_C2_KHS5U_L08769; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e9ce71a-9dc9-4bc9-8bdc-49e9e70dfff9

The open-access MAF lists 1,644 somatic variants for this specimen: 574 protein-altering or splice-affecting, 266 silent, 804 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 486, 3'UTR 396, Silent 266, Intron 213, 5'UTR 101, Nonsense Mutation 56, 5'Flank 40, 3'Flank 35, RNA 19, Splice Region 15, Splice Site 9, Translation Start Site 3.

Variants (750 of 1,644; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH7A1 | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs994001880, CM0910576; ClinVar: likely pathogenic; called by muse, mutect2
- C3orf70 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 34/108 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs757159118, COSV58586480, COSV58587413, COSV58588338; called by muse, mutect2, varscan2
- CFTR | c.2395C>T p.Q799* | Nonsense Mutation (SNP) | VAF 113/241 reads (47%) | catalogued as rs984281283, CM160262, COSV50134361; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 11/257 reads (4%) | hotspot (GDC flag); catalogued as rs866380588, COSV52660737, COSV52978302; ClinVar: pathogenic; called by muse, mutect2
- TPM1 | c.519G>C p.E173D | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs886037905; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.4231G>A p.E1411K | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.021); catalogued as rs368828473, COSV52208810; called by muse, mutect2, varscan2
- ABCA9 | c.4075G>A p.E1359K | Missense Mutation (SNP) | VAF 50/338 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV60623808; called by muse, mutect2, varscan2
- AC091959.1 | c.2986C>T p.R996W | Missense Mutation (SNP) | VAF 25/209 reads (12%) | catalogued as rs369422757, COSV57943108; called by muse, mutect2, varscan2
- AC098582.1 | c.2952C>G p.I984M | Missense Mutation (SNP) | VAF 57/178 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52019128; called by muse, mutect2, varscan2
- ACSM1 | c.1519C>T p.R507* | Nonsense Mutation (SNP) | VAF 27/295 reads (9%) | catalogued as rs376177196; called by muse, mutect2
- ADAMTS10 | c.590G>A p.R197K | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.98); PolyPhen possibly damaging (0.68); catalogued as rs1161726059; called by muse, mutect2, varscan2
- ADAT2 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 104/163 reads (64%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs372845883; called by muse, mutect2, varscan2
- ADCY5 | c.2248G>T p.E750* | Nonsense Mutation (SNP) | VAF 7/128 reads (5%) | catalogued as rs1553724982; called by muse, mutect2
- ADGRA2 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 58/99 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as rs766211508; called by muse, mutect2, varscan2
- ADGRE2 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs1357577914; called by muse, mutect2
- ADGRL2 | c.3988C>T p.Q1330* (on ENST00000370717 / NM_001366005.1; = p.Q1274* on NM_012302.4) | Nonsense Mutation (SNP) | VAF 12/271 reads (4%) | catalogued as COSV54691602; called by muse, mutect2
- AKAP6 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1200402936; called by muse, mutect2
- ANKRD34B | c.1127C>T p.S376L | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as COSV100103335, COSV58614554; called by muse, mutect2
- AOX1 | c.1391G>C p.G464A | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV101022222; called by muse, mutect2, varscan2
- AP3B2 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 126/303 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV55611533; called by muse, mutect2, varscan2
- APOB | c.6994G>A p.E2332K | Missense Mutation (SNP) | VAF 119/247 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV51922005, COSV51947791; called by muse, mutect2, varscan2
- ARNTL | c.1010C>T p.S337F (on ENST00000403290 / NM_001297719.2; = p.S336F on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/235 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs148464006; called by muse, mutect2, varscan2
- ATP6V1F | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 15/221 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV50800212; called by muse, mutect2
- ATP8B1 | c.1811C>T p.S604F | Missense Mutation (SNP) | VAF 88/211 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99377884; called by muse, mutect2, varscan2
- BCL9 | c.1227G>A p.M409I | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.168); catalogued as rs1553204521; called by muse, mutect2, varscan2
- BDH1 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 96/179 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100827194, COSV64017737; called by muse, mutect2, varscan2
- BPNT1 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 82/198 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.917); catalogued as rs1453864571; called by muse, mutect2, varscan2
- BTBD10 | c.346C>G p.Q116E | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.099); catalogued as COSV99533682; called by muse, mutect2, varscan2
- BTN3A3 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.784); catalogued as rs772974735; called by muse, mutect2
- BTNL9 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 49/190 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.807); catalogued as COSV59798661; called by muse, mutect2, varscan2
- C12orf29 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV63554430; called by muse, mutect2, varscan2
- CACNA1G | c.3020C>T p.S1007L | Missense Mutation (SNP) | VAF 51/289 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs765076871; called by muse, mutect2, varscan2
- CACNB2 | c.422C>T p.S141L (on ENST00000324631 / NM_201596.3; = p.S86L on NM_000724.4) | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs1564620358; called by muse, mutect2, varscan2
- CAGE1 | c.207G>C p.K69N | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV99699775; called by muse, mutect2, varscan2
- CASP10 | c.1033C>T p.H345Y (on ENST00000272879 / NM_032974.5; = p.H302Y on NM_001230.5) | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1559309100; called by muse, mutect2
- CBL | c.2696C>T p.S899F | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as COSV99876977; called by muse, mutect2, varscan2
- CCDC174 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1232312134; called by muse, mutect2
- CCDC191 | c.2128G>C p.E710Q | Missense Mutation (SNP) | VAF 156/479 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.656); catalogued as rs1331329651; called by muse, mutect2, varscan2
- CEP55 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 63/237 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV65185231; called by muse, mutect2, varscan2
- CFAP20DC | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.884); catalogued as COSV55928425; called by muse, mutect2, varscan2
- CFHR2 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs566072611, COSV66381546; called by muse, mutect2
- CHADL | c.1489C>T p.P497S | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1217406159, COSV99346592; called by muse, mutect2
- CKB | c.193+7G>A | Splice Region (SNP) | VAF 23/54 reads (43%) | catalogued as rs767588959; called by muse, mutect2, varscan2
- CNOT4 | c.757C>T p.Q253* | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as COSV100211297; called by muse, mutect2, varscan2
- CNTNAP5 | c.1306G>A p.V436I | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs145480371; called by muse, mutect2, varscan2
- COL15A1 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 133/223 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs759553086, COSV66641348; called by muse, mutect2, varscan2
- COL15A1 | c.3626C>T p.S1209L | Missense Mutation (SNP) | VAF 33/246 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs772268496; called by muse, mutect2, varscan2
- COL4A2 | c.2909G>A p.R970Q | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1229599196, COSV100847510; called by muse, mutect2, varscan2
- COL4A4 | c.3676C>T p.R1226C | Missense Mutation (SNP) | VAF 90/193 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs769191749; called by muse, mutect2, varscan2
- CRYBG2 | c.4075C>T p.Q1359* | Nonsense Mutation (SNP) | VAF 23/59 reads (39%) | catalogued as COSV57485610; called by muse, mutect2, varscan2
- CUX1 | c.1057G>C p.E353Q (on ENST00000292535 / NM_181552.4; = p.E364Q on NM_001913.5) | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.214); catalogued as COSV52890619; called by muse, mutect2, varscan2
- CXCL16 | c.517C>A p.H173N | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV53412066; called by muse, mutect2, varscan2
- DDX3X | c.1226C>G p.S409C (on ENST00000399959; = p.S410C on NM_001356.5) | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV67863744; called by muse, mutect2, varscan2
- DENND4A | c.1036G>T p.E346* | Nonsense Mutation (SNP) | VAF 15/237 reads (6%) | catalogued as rs866161244; called by muse, mutect2
- DMBX1 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 58/110 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs760128987, COSV100760898; called by muse, mutect2, varscan2
- DMRTA2 | c.1538C>T p.S513L | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs867513969; called by muse, mutect2, varscan2
- DNAH12 | c.2542C>G p.R848G (on ENST00000351747; = p.R871G on NM_001366028.2) | Missense Mutation (SNP) | VAF 48/268 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as COSV100696659; called by muse, mutect2, varscan2
- DNAH2 | c.11501G>T p.R3834L | Missense Mutation (SNP) | VAF 40/258 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.039); catalogued as rs368019673; called by muse, mutect2, varscan2
- DNAH6 | c.10402G>A p.E3468K | Missense Mutation (SNP) | VAF 76/306 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1446793803; called by muse, mutect2, varscan2
- DNAH7 | c.5857C>G p.L1953V | Missense Mutation (SNP) | VAF 99/184 reads (54%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as COSV100417675, COSV100417704; called by muse, mutect2, varscan2
- DPYS | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100680106; called by muse, mutect2
- DSP | c.5068G>A p.E1690K | Missense Mutation (SNP) | VAF 69/218 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV65791006; called by muse, mutect2, varscan2
- DUOX1 | c.1872C>G p.F624L | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs748573034; called by muse, mutect2, varscan2
- EFCAB5 | c.1765C>T p.R589C | Missense Mutation (SNP) | VAF 147/592 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as rs774341916; called by muse, mutect2, varscan2
- EIF3M | c.831G>A p.M277I | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs866389469, COSV58804236; called by muse, mutect2, varscan2
- ELFN1 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.919); catalogued as rs1321763812; called by muse, mutect2, varscan2
- ENTPD5 | c.1084+1G>A p.X362_splice | Splice Site (SNP) | VAF 48/193 reads (25%) | catalogued as rs777908019; called by muse, mutect2, varscan2
- EPHA6 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1351182206, COSV67576229; called by muse, mutect2
- EPHA6 | c.2249G>A p.R750K (on ENST00000389672 / NM_001080448.3; = p.R142K on NM_173655.4) | Missense Mutation (SNP) | VAF 82/163 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV67598236; called by muse, mutect2, varscan2
- EPS8L2 | c.822G>C p.Q274H | Missense Mutation (SNP) | VAF 36/321 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.132); catalogued as rs1444033270, COSV59346785, COSV59348887; called by muse, mutect2, varscan2
- ERBB3 | c.1800C>G p.I600M | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57246651, COSV57263913; called by muse, mutect2, varscan2
- ERICH6 | c.1480C>T p.H494Y | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.678); catalogued as rs1049393562; called by muse, mutect2, varscan2
- EVC | c.712C>T p.Q238* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as rs770396892; called by muse, mutect2, varscan2
- FADS2 | c.981G>A p.R327= | Splice Region (SNP) | VAF 7/104 reads (7%) | catalogued as rs1481466571; called by muse, mutect2
- FAM160A2 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99792592; called by muse, mutect2, varscan2
- FAM161A | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs184627338, COSV100281296; called by muse, mutect2, varscan2
- FAM20A | c.639G>A p.Q213= | Splice Region (SNP) | VAF 19/89 reads (21%) | catalogued as COSV99873332; called by muse, mutect2, varscan2
- FAM222B | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 55/113 reads (49%) | catalogued as COSV99049867; called by muse, mutect2, varscan2
- FAM8A1 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.042); catalogued as rs563770775; called by muse, mutect2
- FAT2 | c.9893C>T p.S3298F | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV55830182; called by muse, mutect2, varscan2
- FBXO21 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV57974262; called by muse, mutect2, varscan2
- FHOD3 | c.2809G>A p.E937K (on ENST00000359247 / NM_001281739.3; = p.E954K on NM_025135.5) | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1310022477; called by muse, mutect2, varscan2
- FLNC | c.4744G>T p.E1582* | Nonsense Mutation (SNP) | VAF 63/210 reads (30%) | catalogued as COSV57962280; called by muse, mutect2, varscan2
- FRMD5 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV68724354; called by muse, mutect2, varscan2
- FRMPD4 | c.1901C>T p.S634L | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.02); catalogued as COSV66219782; called by muse, mutect2, varscan2
- FRYL | c.3994G>A p.E1332K | Missense Mutation (SNP) | VAF 124/264 reads (47%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs1182710434; called by muse, mutect2, varscan2
- GADD45G | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.199); catalogued as rs774642149; called by muse, mutect2
- GATA3 | c.653C>A p.P218H | Missense Mutation (SNP) | VAF 189/411 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV60516820; called by muse, mutect2, varscan2
- GFER | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as COSV50191860; called by muse, mutect2, varscan2
- GMPPB | c.542C>A p.A181E | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs777909174; called by muse, mutect2, varscan2
- GOLGA4 | c.1666C>T p.R556W | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.528); catalogued as rs113898889; called by muse, mutect2, varscan2
- GOLGA4 | c.5678G>A p.R1893K | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62709340; called by muse, mutect2
- GPD1L | c.363C>G p.I121M | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as COSV56989336; called by muse, mutect2, varscan2
- GRAMD1B | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 52/185 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as rs774167637; called by muse, mutect2, varscan2
- GREB1L | c.3322G>A p.D1108N | Missense Mutation (SNP) | VAF 38/42 reads (90%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1487281383; called by muse, mutect2, varscan2
- H1-4 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 67/168 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.275); catalogued as COSV56800756; called by muse, mutect2, varscan2
- HES1 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 54/317 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51684314, COSV51684639; called by muse, mutect2, varscan2
- HFM1 | c.1343C>T p.A448V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV99646754; called by muse, mutect2, varscan2
- HGS | c.1142C>G p.S381C | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.106); catalogued as rs566201558, COSV100230630; called by muse, mutect2, varscan2
- HIRIP3 | c.1199C>G p.S400C | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV54230979; called by muse, mutect2, varscan2
- HRNR | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 180/411 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1408448417, COSV100913896; called by muse, mutect2, varscan2
- HSD3B1 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV52490861; called by muse, mutect2, varscan2
- IGFBP5 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1180382055; called by muse, mutect2, varscan2
- IGLV3-1 | c.251A>T p.N84I | Missense Mutation (SNP) | VAF 83/84 reads (99%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as rs373605544; called by muse, mutect2, varscan2
- IGSF8 | c.1574G>A p.R525Q | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs774161453, COSV100081610; called by muse, mutect2, varscan2
- IGSF9B | c.3544C>T p.R1182W | Missense Mutation (SNP) | VAF 82/171 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs765118637, COSV58063635; called by muse, mutect2, varscan2
- IL13RA2 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as rs377163094, COSV54564696; called by muse, mutect2
- IL17RD | c.1967C>T p.S656L | Missense Mutation (SNP) | VAF 81/172 reads (47%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs768497234; called by muse, mutect2, varscan2
- INSM2 | c.1649C>T p.S550L | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV51882523; called by muse, mutect2, varscan2
- IRF2BPL | c.1176C>G p.F392L | Missense Mutation (SNP) | VAF 101/158 reads (64%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as COSV53148044; called by muse, mutect2, varscan2
- ITGAL | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 47/84 reads (56%) | catalogued as COSV63321370; called by muse, mutect2, varscan2
- JAK2 | c.1778C>T p.S593F | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1368235418, COSV67585095; called by muse, mutect2
- JPH3 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 5/138 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52471048; called by muse, mutect2
- JPH3 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.484); catalogued as rs755951557, COSV52466554; called by muse, mutect2
- KANK3 | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.127); catalogued as COSV58360957; called by muse, mutect2, varscan2
- KDM4A | c.3100G>C p.E1034Q | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as rs994500438, COSV53517089; called by muse, mutect2
- KDR | c.3842C>G p.S1281C | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.401); catalogued as COSV55758844; called by muse, mutect2, varscan2
- KEAP1 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 57/201 reads (28%) | SIFT tolerated (0.92); PolyPhen benign (0.057); catalogued as COSV99407622; called by muse, mutect2, varscan2
- KIF7 | c.3835C>T p.R1279C | Missense Mutation (SNP) | VAF 133/349 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749221779, COSV51543159; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KNL1 | c.1365C>G p.F455L (on ENST00000346991 / NM_170589.5; = p.F429L on NM_144508.5) | Missense Mutation (SNP) | VAF 21/480 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.067); catalogued as rs1273657787, COSV61153155; called by muse, mutect2
- KNOP1 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs754332903; called by muse, mutect2, varscan2
- LRP1B | c.9061G>A p.D3021N | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.07); catalogued as COSV67199554; called by muse, mutect2
- LRP4 | c.5095G>A p.E1699K | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV66136163; called by muse, mutect2
- LRRCC1 | c.2914C>G p.Q972E | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV64483980; called by muse, mutect2, varscan2
- LSM14A | c.1327G>A p.G443R | Missense Mutation (SNP) | VAF 7/177 reads (4%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.999); catalogued as rs1329578601; called by muse, mutect2
- LSR | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.716); catalogued as COSV100670694; called by muse, mutect2, varscan2
- LSR | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.206); catalogued as COSV100670479; called by muse, mutect2, varscan2
- LTBP4 | c.2750C>T p.S917F (on ENST00000308370 / NM_001042544.1; = p.S880F on NM_003573.2) | Missense Mutation (SNP) | VAF 137/277 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs984910753; called by muse, mutect2, varscan2
- MAP1LC3A | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as rs1357145981, COSV54159932; called by muse, mutect2, varscan2
- MAP9 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); catalogued as COSV60905514; called by muse, mutect2, varscan2
- MAST1 | c.1400G>C p.G467A | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1162325894; called by muse, mutect2, varscan2
- MBLAC1 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs1214216720, COSV99498738; called by muse, mutect2
- MDP1 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); catalogued as rs774318483; called by muse, mutect2, varscan2
- MEF2B | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50763984, COSV99364605; called by muse, mutect2, varscan2
- MISP3 | c.563C>T p.P188L (on ENST00000269720; = p.P46L on NM_001291291.2) | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as rs896435341; called by muse, mutect2
- MLH3 | c.2570C>T p.S857F | Missense Mutation (SNP) | VAF 57/104 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV53158114; called by muse, mutect2, varscan2
- MLPH | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs545517153, COSV52819418; called by muse, mutect2, varscan2
- MMP19 | c.1289C>T p.S430L | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs372055008, COSV59450945; called by muse, mutect2, varscan2
- MTG2 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs759174396; called by muse, mutect2, varscan2
- MUC4 | c.6421G>A p.D2141N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.55); catalogued as COSV62192089; called by muse, varscan2
- MUC5AC | c.3146C>T p.T1049M | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0); catalogued as rs960434531; called by muse, mutect2
- MYH2 | c.1669G>A p.D557N | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as COSV99821294; called by muse, mutect2, varscan2
- MYLK | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 9/269 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.793); catalogued as COSV60604962; called by muse, mutect2
- MYO18A | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.041); catalogued as rs769235341, COSV100572742; called by muse, mutect2, varscan2
- MYO7B | c.3356C>A p.S1119* | Nonsense Mutation (SNP) | VAF 91/348 reads (26%) | catalogued as COSV67348497; called by muse, mutect2, varscan2
- MYOM2 | c.3391C>T p.H1131Y | Missense Mutation (SNP) | VAF 110/124 reads (89%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs774472981; called by muse, mutect2, varscan2
- MYT1L | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 12/368 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1240453695, COSV101221591; called by muse, mutect2
- NFAT5 | c.1889C>T p.S630L | Missense Mutation (SNP) | VAF 62/121 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.154); catalogued as rs768836791; called by muse, mutect2, varscan2
- NOSTRIN | c.261-1G>A p.X87_splice (on ENST00000317647 / NM_001039724.4; = p.X9_splice on NM_052946.3) | Splice Site (SNP) | VAF 24/90 reads (27%) | catalogued as COSV100473291; called by muse, mutect2, varscan2
- NPHS1 | c.1783C>T p.R595W | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs781415913; called by muse, mutect2, varscan2
- NUP42 | c.474G>C p.L158F | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51729179; called by muse, mutect2, varscan2
- NYAP1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 150/419 reads (36%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.974); catalogued as COSV100278593; called by muse, varscan2
- OR10A2 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 114/368 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.32); catalogued as rs1476675331; called by muse, mutect2, varscan2
- OR10H3 | c.926G>A p.R309K | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as rs753368694, COSV59944205; called by muse, mutect2
- OR1B1 | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 65/353 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as rs757251330, COSV59171979; called by muse, mutect2, varscan2
- OR8G2P | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); catalogued as rs755860978; called by muse, mutect2, varscan2
- OSBPL1A | c.2464G>A p.E822K (on ENST00000319481 / NM_080597.4; = p.E309K on NM_018030.4) | Missense Mutation (SNP) | VAF 62/115 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV60195751; called by muse, mutect2, varscan2
- PAK4 | c.44C>A p.S15Y | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs1439968045; called by muse, mutect2
- PANK3 | c.937-1G>A p.X313_splice | Splice Site (SNP) | VAF 15/45 reads (33%) | catalogued as COSV53323862; called by muse, mutect2, varscan2
- PATZ1 | c.295G>A p.G99R | Missense Mutation (SNP) | VAF 130/148 reads (88%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.934); catalogued as COSV53231513, COSV99315713; called by muse, mutect2, varscan2
- PCDHGA12 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.158); catalogued as rs539719239; called by muse, mutect2, varscan2
- PCSK6 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs760045382; called by muse, mutect2, varscan2
- PHF3 | c.3551C>T p.S1184F | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV50326110; called by muse, mutect2, varscan2
- PHIP | c.1603C>T p.H535Y | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51506446, COSV99243633; called by muse, mutect2, varscan2
- PHTF2 | c.1042C>T p.R348C (on ENST00000248550 / NM_001366089.1; = p.R310C on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/131 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs1157684887, COSV50324762; called by muse, mutect2
- PKD2L2 | c.1639del p.E547Nfs*19 | Frame Shift Del (DEL) | VAF 19/88 reads (22%) | catalogued as rs1337500656; called by mutect2, pindel, varscan2
- PLA2G4A | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs960702017; called by muse, mutect2
- PLBD1 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV99554147; called by muse, mutect2, varscan2
- PLIN4 | c.3991G>C p.E1331Q (on ENST00000301286; = p.E1346Q on NM_001367868.2) | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs1187559215; called by muse, mutect2, varscan2
- PON2 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs770816371; called by muse, mutect2, varscan2
- PPIG | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV53643260; called by muse, mutect2, varscan2
- PPP2R5D | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as COSV100029038; called by muse, mutect2, varscan2
- PRELID1 | c.125G>C p.R42P | Missense Mutation (SNP) | VAF 97/235 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as COSV57463569; called by muse, mutect2, varscan2
- PRICKLE2 | c.1921G>A p.E641K (on ENST00000295902; = p.E585K on NM_198859.4) | Missense Mutation (SNP) | VAF 27/210 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99896845; called by muse, mutect2, varscan2
- PRR14L | c.4477C>T p.R1493W | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs577725143; called by muse, mutect2, varscan2
- PRRC2B | c.4298G>A p.R1433Q | Missense Mutation (SNP) | VAF 77/118 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748973480; called by muse, mutect2, varscan2
- PTCH2 | c.3018C>G p.I1006M | Missense Mutation (SNP) | VAF 91/159 reads (57%) | SIFT tolerated (0.34); PolyPhen benign (0.039); catalogued as rs767257214, COSV64710113; called by muse, mutect2, varscan2
- PTPRF | c.3541G>A p.E1181K | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as rs1315505195; called by muse, varscan2
- RABEPK | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 102/173 reads (59%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs186253137; called by muse, mutect2, varscan2
- RAPGEFL1 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs747932126; called by muse, mutect2, varscan2
- RCAN2 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57819603; called by muse, mutect2, varscan2
- RIPOR2 | c.1813G>C p.E605Q | Missense Mutation (SNP) | VAF 72/209 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.942); catalogued as COSV99428481; called by muse, mutect2, varscan2
- RNMT | c.1250C>T p.A417V | Missense Mutation (SNP) | VAF 35/42 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs985702261; called by muse, mutect2, varscan2
- RPAP2 | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs916382901; called by muse, mutect2, varscan2
- RPS24 | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs914531695, COSV71268127; called by muse, mutect2, varscan2
- RTCB | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/190 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.838); catalogued as rs1377838485; called by muse, mutect2
- SAMSN1 | c.11G>A p.R4K | Missense Mutation (SNP) | VAF 8/187 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV53470061; called by muse, mutect2
- SCUBE2 | c.2260C>T p.R754* (on ENST00000649792 / NM_001367977.2; = p.R697* on NM_020974.3) | Nonsense Mutation (SNP) | VAF 14/116 reads (12%) | catalogued as rs767271950; called by muse, mutect2, varscan2
- SECISBP2L | c.2623G>A p.E875K (on ENST00000559471 / NM_001193489.2; = p.E830K on NM_014701.4) | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV55936894; called by muse, mutect2
- SEMA3A | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54881971, COSV54888048; called by muse, mutect2
- SH3PXD2B | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as rs374493298; called by muse, mutect2, varscan2
- SHQ1 | c.1444G>C p.D482H | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.436); catalogued as COSV57764395; called by muse, mutect2
- SHROOM1 | c.1897G>C p.D633H | Missense Mutation (SNP) | VAF 74/175 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.89); catalogued as rs1424775880; called by muse, mutect2, varscan2
- SIRT7 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.022); catalogued as rs1408812376; called by muse, mutect2
- SLA2 | c.651G>A p.W217* | Nonsense Mutation (SNP) | VAF 40/250 reads (16%) | catalogued as COSV53410101; called by muse, mutect2, varscan2
- SLC17A5 | c.979-1G>C p.X327_splice | Splice Site (SNP) | VAF 28/34 reads (82%) | catalogued as COSV63287223; called by muse, mutect2, varscan2
- SLC27A5 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 65/431 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1189055667, COSV54021591, COSV99564406; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC7A3 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 17/182 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as rs868644826, COSV53227672; called by muse, mutect2
- SLIT3 | c.2167C>T p.P723S | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.014); catalogued as COSV60590804; called by muse, mutect2, varscan2
- SMG1 | c.8908C>G p.Q2970E | Missense Mutation (SNP) | VAF 68/88 reads (77%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV101245149, COSV67173998; called by muse, mutect2, varscan2
- SP6 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs770271422, COSV60616999; called by muse, mutect2, varscan2
- SPIN4 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as rs782031647; called by muse, mutect2
- SPOCK1 | c.961C>T p.Q321* | Nonsense Mutation (SNP) | VAF 136/283 reads (48%) | catalogued as COSV56463788; called by muse, mutect2, varscan2
- STOX1 | c.1285C>T p.R429* | Nonsense Mutation (SNP) | VAF 78/241 reads (32%) | catalogued as rs1198618948, COSV53814313, COSV53818315; called by muse, mutect2, varscan2
- SYT4 | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV54901955, COSV99673969; called by muse, mutect2, varscan2
- TBC1D21 | c.134C>A p.S45* | Nonsense Mutation (SNP) | VAF 18/226 reads (8%) | catalogued as COSV55995276; called by muse, mutect2
- TCF3 | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); catalogued as rs1365077546; called by muse, mutect2
- TFAP2D | c.1079G>A p.G360E | Missense Mutation (SNP) | VAF 21/485 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV50418310; called by muse, mutect2
- TKTL2 | c.1679T>A p.V560D | Missense Mutation (SNP) | VAF 77/156 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV54918060, COSV54921236; called by muse, mutect2, varscan2
- TMCO4 | c.37C>A p.Q13K | Missense Mutation (SNP) | VAF 24/25 reads (96%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs534456252, COSV53872305, COSV99615488, COSV99616333; called by muse, mutect2, varscan2
- TNXB | c.7720G>A p.E2574K (on ENST00000647633; = p.E2327K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.939); catalogued as rs764604500, COSV64475307; called by muse, mutect2, varscan2
- TPBGL | c.1148G>C p.*383Sext*18 | Nonstop Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as COSV73206796; called by muse, mutect2, varscan2
- TPM1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 17/224 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as COSV51260692; called by muse, mutect2
- TRABD2B | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs1474215819, COSV71107984; called by muse, mutect2
- TRIM23 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.483); catalogued as rs771639235; called by muse, mutect2, varscan2
- TRIM39-RPP21 | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 10/164 reads (6%) | catalogued as rs1335930540; called by muse, mutect2
- TRIM9 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.054); catalogued as COSV53626441; called by muse, mutect2, varscan2
- TRPV5 | c.1768G>A p.D590N | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.627); catalogued as COSV99520831; called by muse, mutect2, varscan2
- TRPV6 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs779880733, COSV100844267, COSV100844379; called by muse, mutect2, varscan2
- TSLP | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 13/377 reads (3%) | SIFT tolerated (0.42); PolyPhen benign (0.046); catalogued as rs867610850, COSV100789155; called by muse, mutect2
- TSR1 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 5/112 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56784914; called by muse, mutect2
- UBR4 | c.15145G>A p.E5049K | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.132); catalogued as rs1267483439; called by muse, mutect2
- USP36 | c.1651C>T p.Q551* | Nonsense Mutation (SNP) | VAF 85/192 reads (44%) | catalogued as COSV100361093; called by muse, mutect2, varscan2
- WDR70 | c.1247C>T p.S416L | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV54284142; called by muse, mutect2, varscan2
- XRN2 | c.2837G>A p.R946K | Missense Mutation (SNP) | VAF 20/672 reads (3%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.931); catalogued as COSV65868814; called by muse, mutect2
- YY1 | c.842G>A p.R281K | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV51761347; called by muse, mutect2, varscan2
- ZCCHC14 | c.679G>A p.V227M (on ENST00000268616; = p.V364M on NM_015144.3) | Missense Mutation (SNP) | VAF 160/172 reads (93%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.7); catalogued as rs747926856; called by muse, mutect2, varscan2
- ZDBF2 | c.6395C>T p.S2132L | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.196); catalogued as COSV99056659; called by muse, mutect2
- ZHX1 | c.880G>C p.D294H | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52876411; called by muse, mutect2
- ZNF225 | c.549G>C p.K183N | Missense Mutation (SNP) | VAF 98/211 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV53471467; called by muse, mutect2, varscan2
- ZNF285 | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 74/190 reads (39%) | catalogued as rs779695369, COSV100449804; called by muse, mutect2, varscan2
- ZNF292 | c.3381T>A p.Y1127* | Nonsense Mutation (SNP) | VAF 106/113 reads (94%) | catalogued as COSV60549074; called by muse, mutect2, varscan2
- ZNF584 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as rs1375926910; called by muse, mutect2
- ZNF667 | c.580C>T p.H194Y | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99410020; called by muse, mutect2, varscan2
- ZNF684 | c.363G>A p.M121I | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs751967901; called by muse, mutect2, varscan2
- ZNF687 | c.3271G>C p.D1091H | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV55020676; called by muse, mutect2
- ZNF862 | c.1706C>G p.S569* | Nonsense Mutation (SNP) | VAF 113/232 reads (49%) | catalogued as COSV56226244; called by muse, mutect2, varscan2
- ZSCAN4 | c.167C>T p.S56L | Missense Mutation (SNP) | VAF 111/344 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as COSV58999394; called by muse, mutect2, varscan2
- ABCA4 | c.2030A>T p.E677V | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCB1 | c.256G>C p.E86Q | Missense Mutation (SNP) | VAF 33/205 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABHD16A | c.1593+3G>A | Splice Region (SNP) | VAF 12/181 reads (7%) | called by muse, mutect2
- ABLIM1 | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- AC093827.5 | c.274C>T p.Q92* | Nonsense Mutation (SNP) | VAF 15/272 reads (6%) | called by muse, mutect2
- AC098582.1 | c.137C>G p.S46C | Missense Mutation (SNP) | VAF 69/169 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- ACKR2 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 17/433 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- ADAMTS17 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ADAMTS20 | c.2065C>T p.Q689* | Nonsense Mutation (SNP) | VAF 22/115 reads (19%) | called by muse, mutect2, varscan2
- ADGRL1 | c.2761-1G>A p.X921_splice (on ENST00000340736 / NM_001008701.3; = p.X916_splice on NM_014921.5) | Splice Site (SNP) | VAF 19/144 reads (13%) | called by muse, mutect2, varscan2
- ADRB1 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- AIMP1 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- AKAP6 | c.4690C>T p.H1564Y | Missense Mutation (SNP) | VAF 69/129 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- AKAP8L | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 8/187 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.447); called by muse, mutect2
- ALB | c.1298T>C p.V433A | Missense Mutation (SNP) | VAF 103/221 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- ALCAM | c.1653G>A p.M551I | Missense Mutation (SNP) | VAF 77/243 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK2 | c.10732G>A p.D3578N | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.6044C>T p.S2015L | Missense Mutation (SNP) | VAF 55/226 reads (24%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD2 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ANP32A | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 121/431 reads (28%) | called by muse, mutect2, varscan2
- ANXA13 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 6/143 reads (4%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.593); called by muse, mutect2
- AP5M1 | c.187G>C p.D63H | Missense Mutation (SNP) | VAF 8/238 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.02); called by muse, mutect2
- APC | c.5143G>A p.D1715N | Missense Mutation (SNP) | VAF 103/220 reads (47%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- APOB | c.12066G>A p.W4022* | Nonsense Mutation (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2
- ASF1B | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 52/347 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- ASNSD1 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 96/239 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ASXL2 | c.2735G>A p.G912E | Missense Mutation (SNP) | VAF 63/202 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ASXL3 | c.5093G>A p.G1698E | Missense Mutation (SNP) | VAF 7/173 reads (4%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2
- ATL2 | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 206/445 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- ATXN3 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 14/356 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.076); called by muse, mutect2
- B2M | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 75/256 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- BAG1 | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 11/232 reads (5%) | called by muse, mutect2
- BAZ2A | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.979); called by muse, mutect2
- BCAS1 | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BCOR | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.445); called by muse, mutect2
- BCORL1 | c.5002C>A p.P1668T | Missense Mutation (SNP) | VAF 64/94 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- BHLHA15 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BTG1 | c.154T>C p.Y52H | Missense Mutation (SNP) | VAF 100/218 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C1orf112 | c.2266G>A p.E756K | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CACHD1 | c.2307G>C p.L769F | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CAMSAP3 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 180/374 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- CASKIN1 | c.1242C>T p.L414= | Splice Region (SNP) | VAF 8/174 reads (5%) | called by muse, mutect2
- CCDC134 | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 159/173 reads (92%) | called by muse, mutect2, varscan2
- CCDC160 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); called by muse, mutect2
- CCDC66 | c.2293C>T p.H765Y (on ENST00000394672 / NM_001353147.1; = p.H731Y on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/176 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- CCDC9 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 59/131 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CDC16 | c.858T>A p.Y286* | Nonsense Mutation (SNP) | VAF 28/55 reads (51%) | called by muse, mutect2, varscan2
- CDK14 | c.124-3C>T | Splice Region (SNP) | VAF 43/265 reads (16%) | called by muse, mutect2, varscan2
- CENPQ | c.219G>A p.W73* | Nonsense Mutation (SNP) | VAF 13/327 reads (4%) | called by muse, mutect2
- CEP112 | c.530G>A p.R177K | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CEP290 | c.6301G>A p.E2101K | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CFAP97D1 | c.207G>C p.K69N | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.019); called by muse, mutect2
- CHD2 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 66/168 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CHD9 | c.622G>C p.V208L | Missense Mutation (SNP) | VAF 10/213 reads (5%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2
- CHD9 | c.4460C>A p.S1487Y | Missense Mutation (SNP) | VAF 93/155 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- CHRNB1 | c.379C>G p.L127V | Missense Mutation (SNP) | VAF 82/439 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CMYA5 | c.11408-6C>G | Splice Region (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- COL4A4 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CROCC | c.4639G>A p.D1547N | Missense Mutation (SNP) | VAF 71/162 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- CROCC2 | c.1387G>C p.E463Q | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- CSMD3 | c.1407C>A p.N469K (on ENST00000297405 / NM_001363185.1; = p.N365K on NM_052900.3) | Missense Mutation (SNP) | VAF 33/43 reads (77%) | SIFT tolerated (0.31); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- CUX2 | c.3046G>T p.E1016* | Nonsense Mutation (SNP) | VAF 37/122 reads (30%) | called by muse, mutect2, varscan2
- CYP4B1 | c.658C>G p.L220V | Missense Mutation (SNP) | VAF 172/185 reads (93%) | SIFT tolerated (0.48); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DAAM2 | c.2896C>T p.Q966* (on ENST00000274867 / NM_001201427.2; = p.Q965* on NM_015345.3) | Nonsense Mutation (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- DCUN1D5 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- DEDD | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2
- DENND1C | c.283C>T p.L95F | Missense Mutation (SNP) | VAF 11/288 reads (4%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.644); called by muse, mutect2
- DENND4A | c.3743G>A p.R1248K | Missense Mutation (SNP) | VAF 9/263 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.437); called by muse, mutect2
- DNAH12 | c.3502G>A p.D1168N (on ENST00000351747; = p.D1191N on NM_001366028.2) | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH9 | c.12358G>C p.D4120H | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAJC4 | c.340G>C p.D114H | Missense Mutation (SNP) | VAF 24/378 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.359); called by muse, mutect2
- DNASE1L2 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 80/144 reads (56%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- DNHD1 | c.2153C>T p.T718I | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DOCK11 | c.2029G>A p.D677N | Missense Mutation (SNP) | VAF 35/39 reads (90%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- DPF2 | c.1039G>C p.D347H | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DRG2 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- DSG3 | c.2854G>A p.D952N | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2
- EFCAB2 | c.700C>T p.L234F (on ENST00000366522; = p.L98F on NM_032328.3) | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- EFCAB7 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EGFLAM | c.2598G>C p.M866I (on ENST00000354891 / NM_001205301.2; = p.M858I on NM_152403.4) | Missense Mutation (SNP) | VAF 128/496 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.132); called by muse, varscan2
- EIF2B2 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.359); called by muse, mutect2
- EIF3B | c.1087G>C p.E363Q | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- EIF3F | c.759G>A p.M253I | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated (0.21); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- EIF4G2 | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 66/227 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- EIF4G2 | c.1277G>A p.G426E | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ELMO2 | c.1359C>G p.I453M | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- ENTPD7 | c.1127G>C p.R376T | Missense Mutation (SNP) | VAF 85/184 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERAP2 | c.1597G>T p.E533* | Nonsense Mutation (SNP) | VAF 31/162 reads (19%) | called by muse, mutect2, varscan2
- ESYT2 | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 31/153 reads (20%) | called by muse, mutect2, varscan2
- F10 | c.590G>T p.S197I | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- FAM221A | c.878C>T p.S293L | Missense Mutation (SNP) | VAF 55/425 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- FANCL | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by muse, mutect2
- FBXL16 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- FCGR2C | c.339G>C p.Q113H | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FCMR | c.324G>A p.M108I | Missense Mutation (SNP) | VAF 89/185 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FGL2 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- FLAD1 | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 215/744 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- FMN1 | c.3333G>C p.E1111D (on ENST00000616417 / NM_001277313.2; = p.E888D on NM_001103184.4) | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- FOXJ3 | c.959C>T p.S320F | Missense Mutation (SNP) | VAF 83/140 reads (59%) | SIFT tolerated (0.16); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- GARNL3 | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- GFI1 | c.1184C>G p.P395R | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLB1L3 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- GLI2 | c.2069C>T p.S690L (on ENST00000361492 / NM_001374353.1; = p.S707L on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/156 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- GMIP | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 159/523 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- GNB5 | c.184G>A p.E62K (on ENST00000261837 / NM_016194.4; = p.E20K on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GPC1 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- GPLD1 | c.2243C>G p.S748C | Missense Mutation (SNP) | VAF 7/153 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2
- GRID2 | c.645G>A p.M215I | Missense Mutation (SNP) | VAF 19/215 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.125); called by muse, mutect2
- GSTCD | c.1540C>T p.H514Y (on ENST00000360505 / NM_001031720.3; = p.H427Y on NM_024751.3) | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.385); called by muse, mutect2
- GSTM2 | c.61C>A p.L21M | Missense Mutation (SNP) | VAF 70/252 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- GUCY1B1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- GZMB | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 21/265 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- HEATR5B | c.3080C>G p.S1027C | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- HECTD4 | c.5435C>A p.S1812* | Nonsense Mutation (SNP) | VAF 41/136 reads (30%) | called by muse, mutect2, varscan2
- HLA-G | c.87G>A p.M29I | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HTT | c.3481C>T p.P1161S | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGF2BP2 | c.1335G>C p.K445N | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- IGF2BP3 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- IGKV5-2 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 105/108 reads (97%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- IHO1 | c.1062G>C p.Q354H | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- IPCEF1 | c.1295C>T p.S432F | Missense Mutation (SNP) | VAF 80/145 reads (55%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IPO5 | c.2696C>T p.S899L | Missense Mutation (SNP) | VAF 14/422 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.465); called by muse, mutect2
- IRS4 | c.508C>T p.L170F | Missense Mutation (SNP) | VAF 9/190 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ITGA6 | c.1690G>A p.E564K (on ENST00000442250; = p.E525K on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ITGA7 | c.1164C>A p.F388L (on ENST00000555728; = p.F344L on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 107/237 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- ITGB1 | c.2165-1G>A p.X722_splice | Splice Site (SNP) | VAF 19/102 reads (19%) | called by muse, mutect2, varscan2
- ITPRID2 | c.3524C>T p.S1175F | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- JAKMIP1 | c.671A>G p.K224R | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KCNJ1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 25/652 reads (4%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2
- KCNN2 | c.274G>T p.G92* (on ENST00000264773; = p.G304* on NM_021614.4) | Nonsense Mutation (SNP) | VAF 25/153 reads (16%) | called by muse, mutect2, varscan2
- KDM5B | c.1690C>G p.H564D | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- KDM5C | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- KIF16B | c.3920G>A p.G1307E | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF23 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 137/432 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF5A | c.2824G>A p.E942K | Missense Mutation (SNP) | VAF 17/485 reads (4%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2
- KLHL4 | c.866C>A p.S289* | Nonsense Mutation (SNP) | VAF 48/79 reads (61%) | called by muse, mutect2, varscan2
- KLHL9 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 88/179 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- KLK7 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- KMT2C | c.13380G>A p.M4460I | Missense Mutation (SNP) | VAF 110/219 reads (50%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- KPNA5 | c.1193G>A p.R398K | Missense Mutation (SNP) | VAF 70/89 reads (79%) | SIFT tolerated (1); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- KRTAP19-2 | c.134G>A p.R45K | Missense Mutation (SNP) | VAF 40/229 reads (17%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- KYNU | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- LAMP5 | c.843G>C p.*281Yext*52 | Nonstop Mutation (SNP) | VAF 25/74 reads (34%) | called by muse, mutect2, varscan2
- LARS1 | c.3271G>A p.D1091N (on ENST00000394434 / NM_020117.11; = p.D1064N on NM_016460.3) | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- LCORL | c.4462G>C p.E1488Q | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- LDAH | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- LDB3 | c.1097C>T p.S366F | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2
- LIFR | c.1579C>G p.Q527E | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0); called by mutect2, varscan2
- LMNB2 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- LRP2 | c.2273C>T p.S758L | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- LRRIQ4 | c.932G>T p.S311I | Missense Mutation (SNP) | VAF 83/165 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LUC7L3 | c.724G>T p.D242Y | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- LYSMD3 | c.632G>T p.G211V | Missense Mutation (SNP) | VAF 25/652 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LZTS3 | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 60/197 reads (30%) | called by muse, mutect2, varscan2
- MAGEA11 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 35/55 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- MAP3K1 | c.3970G>A p.E1324K | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- MAP4K1 | c.116C>T p.S39L | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- MAST4 | c.7531G>A p.G2511S (on ENST00000403625 / NM_001164664.2; = p.G2322S on NM_015183.3) | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MCM10 | c.999C>G p.F333L (on ENST00000484800 / NM_182751.3; = p.F332L on NM_018518.5) | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.362); called by muse, mutect2
- METTL2B | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 26/715 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); called by muse, mutect2
- MFAP3L | c.195G>C p.L65F | Missense Mutation (SNP) | VAF 11/220 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.432); called by muse, mutect2
- MFSD9 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 13/474 reads (3%) | SIFT tolerated (0.69); PolyPhen benign (0.001); called by muse, mutect2
- MICAL2 | c.1940C>T p.S647L | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MICALL2 | c.2080T>C p.W694R | Missense Mutation (SNP) | VAF 82/192 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MKRN2 | c.991G>C p.E331Q | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- MOCS3 | c.218G>A p.G73D | Missense Mutation (SNP) | VAF 73/231 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MTA1 | c.1026G>C p.L342F | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- MYO5A | c.4048G>A p.E1350K | Missense Mutation (SNP) | VAF 70/135 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- MYO7B | c.4468G>A p.E1490K | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- NALCN | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 12/263 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); called by muse, mutect2
- NCDN | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- NCKAP1 | c.432G>A p.M144I | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- NDUFA6 | c.386G>C p.*129Sext*13 | Nonstop Mutation (SNP) | VAF 8/250 reads (3%) | called by muse, mutect2
- NEB | c.18412G>C p.E6138Q | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NEFH | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.187); called by muse, mutect2
- NFRKB | c.1906C>T p.P636S (on ENST00000446488 / NM_001143835.2; = p.P661S on NM_006165.3) | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NIFK | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 42/76 reads (55%) | called by muse, mutect2, varscan2
- NIN | c.5041G>C p.D1681H (on ENST00000382041 / NM_182946.1; = p.D968H on NM_016350.4) | Missense Mutation (SNP) | VAF 6/173 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2
- NLRC5 | c.3847A>G p.I1283V | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- NLRP14 | c.1684C>T p.Q562* | Nonsense Mutation (SNP) | VAF 29/100 reads (29%) | called by muse, mutect2, varscan2
- NPFFR1 | c.879C>G p.I293M | Missense Mutation (SNP) | VAF 62/268 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.637); called by muse, varscan2
- NPHS1 | c.1459G>T p.E487* | Nonsense Mutation (SNP) | VAF 33/74 reads (45%) | called by muse, mutect2, varscan2
- NSD2 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 76/203 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NSF | c.1440C>A p.F480L | Missense Mutation (SNP) | VAF 19/316 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); called by muse, mutect2
- NUDT9 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 12/332 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- OCM2 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 77/371 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- OR13G1 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 132/257 reads (51%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- OR2B6 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 11/386 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- OR2T3 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 64/472 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- OTX1 | c.222G>C p.K74N | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PC | c.3261C>G p.I1087M | Missense Mutation (SNP) | VAF 64/135 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- PCDH11X | c.1415C>A p.T472N | Missense Mutation (SNP) | VAF 92/100 reads (92%) | SIFT deleterious (0.04); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- PCNT | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 69/182 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PEX6 | c.2298C>T p.L766= | Splice Region (SNP) | VAF 38/159 reads (24%) | called by muse, mutect2, varscan2
- PGF | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PGPEP1 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 104/238 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PHOSPHO2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 19/448 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.175); called by muse, mutect2
- PI16 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIGG | c.1483G>A p.E495K (on ENST00000453061 / NM_001127178.3; = p.E487K on NM_017733.4) | Missense Mutation (SNP) | VAF 188/604 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- PIK3C3 | c.1995G>C p.L665F | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- PIN4 | c.358C>T p.Q120* (on ENST00000664196; = p.Q95* on NM_006223.4) | Nonsense Mutation (SNP) | VAF 33/100 reads (33%) | called by muse, mutect2, varscan2
- PINX1 | c.19+3G>A | Splice Region (SNP) | VAF 78/128 reads (61%) | called by muse, varscan2
- PITRM1 | c.1750C>T p.P584S | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- PLEC | c.7672G>A p.E2558K (on ENST00000322810 / NM_201380.4; = p.E2448K on NM_000445.5) | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); called by muse, mutect2
- PNPLA2 | c.313G>C p.D105H | Missense Mutation (SNP) | VAF 10/267 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- POC1B | c.301C>T p.H101Y | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POLDIP2 | c.742T>G p.F248V | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2
- POLR1C | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.082); called by muse, mutect2
- PPM1H | c.1283C>T p.S428L | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PPP1R10 | c.192C>T p.V64= | Splice Region (SNP) | VAF 9/148 reads (6%) | called by muse, mutect2
- PPP4R3B | c.2131G>T p.E711* (on ENST00000616407 / NM_001122964.3; = p.E626* on NM_020463.4) | Nonsense Mutation (SNP) | VAF 8/157 reads (5%) | called by muse, mutect2
- PROSER1 | c.259C>G p.L87V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PRRC2C | c.1286G>A p.G429E (on ENST00000367742; = p.G427E on NM_015172.4) | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- PRSS12 | c.2086C>T p.H696Y | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PSMD13 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PTCHD3 | c.2203G>C p.D735H | Missense Mutation (SNP) | VAF 6/168 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- PTH2R | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 28/168 reads (17%) | called by muse, mutect2, varscan2
- PTPRF | c.2887G>C p.E963Q | Missense Mutation (SNP) | VAF 118/196 reads (60%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- RAB11FIP1 | c.150G>C p.E50D | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); called by muse, mutect2
- RAB11FIP5 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- RAB40A | c.-70-7C>T | Splice Region (SNP) | VAF 10/159 reads (6%) | called by muse, mutect2
- RABGAP1 | c.3138G>C p.K1046N | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- RASA1 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 16/493 reads (3%) | SIFT tolerated (0.41); PolyPhen benign (0.056); called by muse, mutect2
- RCL1 | c.358G>C p.V120L | Missense Mutation (SNP) | VAF 65/208 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- RGL1 | c.1691C>T p.S564L (on ENST00000360851 / NM_001297672.2; = p.S599L on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- RIF1 | c.4931A>C p.D1644A | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- RNF135 | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF168 | c.681-7C>T | Splice Region (SNP) | VAF 14/139 reads (10%) | called by muse, mutect2, varscan2
- RPL7L1 | c.*7-5C>G | Splice Region (SNP) | VAF 97/252 reads (38%) | called by muse, mutect2, varscan2
- RRBP1 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- RYR2 | c.5182C>T p.P1728S | Missense Mutation (SNP) | VAF 96/220 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SALL3 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.165); called by muse, mutect2
- SALL4 | c.1238C>T p.S413F | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- SAMD14 | c.211-7C>T | Splice Region (SNP) | VAF 21/94 reads (22%) | called by muse, mutect2, varscan2
- SAP30BP | c.890C>A p.S297Y | Missense Mutation (SNP) | VAF 83/183 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCFD2 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 66/220 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SCML4 | c.902C>G p.S301W | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- SCN5A | c.5974G>A p.G1992R (on ENST00000333535 / NM_198056.3; = p.G1991R on NM_000335.5) | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCYL2 | c.2599C>T p.Q867* | Nonsense Mutation (SNP) | VAF 32/203 reads (16%) | called by muse, mutect2, varscan2
- SDCBP2 | c.643C>G p.L215V (on ENST00000339987 / NM_001199784.1; = p.L130V on NM_015685.5) | Missense Mutation (SNP) | VAF 105/403 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SEC24B | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 21/338 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2
- SEMA6D | c.658+1G>A p.X220_splice | Splice Site (SNP) | VAF 54/108 reads (50%) | called by muse, mutect2, varscan2
- SHANK1 | c.6100G>A p.D2034N | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, varscan2
- SHF | c.766C>A p.P256T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- SIDT2 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 11/290 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.053); called by muse, mutect2
- SIL1 | c.646-1G>C p.X216_splice | Splice Site (SNP) | VAF 13/90 reads (14%) | called by muse, mutect2, varscan2
- SLC22A16 | c.787T>G p.L263V | Missense Mutation (SNP) | VAF 113/115 reads (98%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- SLC22A5 | c.333G>C p.E111D | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC30A3 | c.117G>T p.E39D | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC38A3 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC43A2 | c.140C>A p.S47Y | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, varscan2
- SLC5A4 | c.526G>C p.D176H | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); called by muse, mutect2
- SLC7A14 | c.1477G>C p.E493Q | Missense Mutation (SNP) | VAF 98/239 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SLC8A1 | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 90/256 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLF1 | c.3147G>A p.M1049I | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SLK | c.2854C>T p.L952F | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SMAD6 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- SNRPA1 | c.444G>C p.Q148H | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.069); called by muse, mutect2
- SNTG1 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 13/15 reads (87%) | called by muse, mutect2, varscan2
- SNX2 | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.031); called by muse, mutect2
- SOCS3 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 12/211 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); called by muse, mutect2
- SP3 | c.1007C>A p.S336* | Nonsense Mutation (SNP) | VAF 23/128 reads (18%) | called by muse, mutect2, varscan2
- SPTB | c.2594G>C p.G865A | Missense Mutation (SNP) | VAF 202/237 reads (85%) | SIFT tolerated (0.26); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- SPTBN1 | c.705G>C p.Q235H | Missense Mutation (SNP) | VAF 12/215 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.179); called by muse, mutect2
- SPTBN1 | c.5548G>C p.E1850Q | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- SPTLC3 | c.251G>A p.R84K | Missense Mutation (SNP) | VAF 22/370 reads (6%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.954); called by muse, mutect2
- SPTY2D1 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 12/229 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.419); called by muse, mutect2
- SRP68 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ST8SIA5 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 10/178 reads (6%) | PolyPhen benign (0.092); called by muse, mutect2
- STARD3 | c.784G>C p.E262Q | Missense Mutation (SNP) | VAF 41/291 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STK17A | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STK32B | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SUB1 | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- SURF1 | c.187C>T p.Q63* | Nonsense Mutation (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2
- TARS3 | c.1700C>T p.S567L | Missense Mutation (SNP) | VAF 55/195 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- TBCCD1 | c.1346_1347del p.C449* | Frame Shift Del (DEL) | VAF 141/328 reads (43%) | called by mutect2, pindel, varscan2
- TDO2 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TDRD10 | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.11); called by muse, mutect2
- TDRD9 | c.3375A>T p.K1125N | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TENM2 | c.5740G>A p.D1914N (on ENST00000518659 / NM_001122679.2; = p.D1675N on NM_001080428.3) | Missense Mutation (SNP) | VAF 67/153 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- TENM3 | c.682A>C p.T228P | Missense Mutation (SNP) | VAF 177/325 reads (54%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- TENM3 | c.7072G>A p.D2358N | Missense Mutation (SNP) | VAF 19/276 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- TEX264 | c.585G>A p.M195I | Missense Mutation (SNP) | VAF 31/218 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEX55 | c.149G>A p.R50K | Missense Mutation (SNP) | VAF 19/286 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.143); called by muse, mutect2
- TGM7 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- TLCD1 | c.25C>G p.L9V | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT tolerated (0.43); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TLNRD1 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 73/261 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- TNPO2 | c.1701C>G p.I567M | Missense Mutation (SNP) | VAF 61/206 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- TPD52 | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 90/104 reads (87%) | called by muse, mutect2, varscan2
- TPRG1 | c.704G>T p.R235I | Missense Mutation (SNP) | VAF 14/277 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.092); called by muse, mutect2
- TRAF2 | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 78/158 reads (49%) | called by muse, varscan2
- TRAF2 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.017); called by muse, mutect2
- TRAF3 | c.-17-1G>A | Splice Site (SNP) | VAF 26/208 reads (13%) | called by muse, mutect2, varscan2
- TRAV14DV4 | c.167G>A p.W56* | Nonsense Mutation (SNP) | VAF 41/74 reads (55%) | called by muse, mutect2, varscan2
- TSGA10 | c.182G>C p.R61T | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- TSHZ3 | c.2106G>C p.L702F | Missense Mutation (SNP) | VAF 52/226 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- TSPYL1 | c.1307C>T p.S436F | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- TSPYL1 | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2
- TTL | c.132G>T p.R44S | Missense Mutation (SNP) | VAF 16/327 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2
- TTLL6 | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 10/294 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- TTYH3 | c.1374C>A p.S458R | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TUT7 | c.1367G>A p.G456D | Missense Mutation (SNP) | VAF 19/249 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- UGGT1 | c.116C>T p.S39L | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- UGT1A9 | c.703C>T p.L235F | Missense Mutation (SNP) | VAF 65/513 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- UNC5C | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 12/51 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- USP11 | c.2242G>A p.E748K (on ENST00000218348; = p.E705K on NM_001371072.1) | Missense Mutation (SNP) | VAF 65/70 reads (93%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- USP24 | c.1549C>T p.Q517* | Nonsense Mutation (SNP) | VAF 40/41 reads (98%) | called by muse, mutect2, varscan2
- USP24 | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 117/127 reads (92%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- USP26 | c.2548G>A p.E850K | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- UTP14A | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- UTP15 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 98/356 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UTP23 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- UXS1 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VARS1 | c.807G>C p.K269N | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- VIPAS39 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 72/118 reads (61%) | SIFT tolerated (0.35); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- VMO1 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 48/309 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- VPS41 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- VPS51 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.17); called by muse, mutect2
- VPS54 | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
- WDFY1 | c.1053C>G p.I351M | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- WDR90 | c.1377C>T p.L459= | Splice Region (SNP) | VAF 17/178 reads (10%) | called by muse, mutect2
- XIRP2 | c.8284G>A p.D2762N (on ENST00000628543; = p.D2937N on NM_152381.6) | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZBED6CL | c.498G>C p.E166D | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ZBTB24 | c.2005C>G p.Q669E | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.6); called by muse, mutect2
- ZFP36 | c.274G>C p.E92Q (on ENST00000594442; = p.E86Q on NM_003407.5) | Missense Mutation (SNP) | VAF 31/218 reads (14%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- ZFP36 | c.916G>A p.E306K (on ENST00000594442; = p.E300K on NM_003407.5) | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- ZKSCAN4 | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 39/283 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ZMYM2 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF407 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 12/277 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.023); called by muse, mutect2
- ZNF428 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ZNF575 | c.694C>T p.Q232* | Nonsense Mutation (SNP) | VAF 12/186 reads (6%) | called by muse, mutect2
- ZNF592 | c.1430C>A p.S477* | Nonsense Mutation (SNP) | VAF 39/348 reads (11%) | called by muse, mutect2, varscan2
- ZNF592 | c.3344C>G p.S1115C | Missense Mutation (SNP) | VAF 44/219 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- ZNF654 | c.2389G>A p.E797K | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF844 | c.430C>G p.Q144E | Missense Mutation (SNP) | VAF 34/698 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2
- ZSWIM8 | c.1924G>A p.E642K | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ABCA5 | c.901C>T p.L301= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs775911299; called by muse, varscan2
- ABCA7 | c.1419C>T p.V473= | Silent (SNP) | VAF 90/214 reads (42%) | called by muse, mutect2, varscan2
- ABCB4 | c.102G>A p.T34= | Silent (SNP) | VAF 5/68 reads (7%) | catalogued as rs1277340029, COSV55932440; called by muse, mutect2
- ABCC1 | c.1365C>T p.L455= | Silent (SNP) | VAF 11/69 reads (16%) | called by muse, mutect2, varscan2
- ABCC4 | c.3090C>T p.R1030= | Silent (SNP) | VAF 82/157 reads (52%) | called by muse, mutect2, varscan2
- ACSS1 | c.1512G>T p.P504= | Silent (SNP) | VAF 23/82 reads (28%) | catalogued as COSV60224948; called by muse, mutect2, varscan2
- ACSS2 | c.609C>T p.I203= | Silent (SNP) | VAF 19/167 reads (11%) | called by muse, mutect2, varscan2
- ADAM8 | c.1956G>A p.G652= | Silent (SNP) | VAF 101/296 reads (34%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.2118G>A p.K706= | Silent (SNP) | VAF 12/184 reads (7%) | called by muse, mutect2
- ADAMTS5 | c.1518C>T p.S506= | Silent (SNP) | VAF 88/195 reads (45%) | catalogued as rs763010212; called by muse, mutect2, varscan2
- ADAMTS8 | c.1380C>T p.F460= | Silent (SNP) | VAF 61/170 reads (36%) | catalogued as COSV104378430, COSV57297672; called by muse, mutect2, varscan2
- AIMP2 | c.474C>G p.V158= | Silent (SNP) | VAF 29/256 reads (11%) | called by muse, mutect2, varscan2
- ALDH4A1 | c.498C>T p.L166= | Silent (SNP) | VAF 17/170 reads (10%) | called by muse, mutect2, varscan2
- ALK | c.270G>A p.S90= | Silent (SNP) | VAF 31/134 reads (23%) | catalogued as rs1430524359; called by muse, mutect2, varscan2
- AMER3 | c.57G>A p.E19= | Silent (SNP) | VAF 37/238 reads (16%) | called by muse, mutect2, varscan2
- ANKRA2 | c.436C>T p.L146= | Silent (SNP) | VAF 64/259 reads (25%) | catalogued as COSV57140510; called by muse, mutect2, varscan2
- ANKRD39 | c.120G>C p.L40= | Silent (SNP) | VAF 71/241 reads (29%) | catalogued as COSV66813560; called by muse, mutect2, varscan2
- APH1A | c.108C>T p.V36= | Silent (SNP) | VAF 77/285 reads (27%) | catalogued as rs782676113; called by muse, mutect2, varscan2
- ARFGEF1 | c.4908C>T p.F1636= | Silent (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- ARHGEF10L | c.3090C>T p.F1030= | Silent (SNP) | VAF 18/82 reads (22%) | called by muse, mutect2, varscan2
- ATF6B | c.12G>A p.L4= | Silent (SNP) | VAF 26/538 reads (5%) | catalogued as COSV64322444; called by muse, mutect2
- ATP10B | c.1254C>A p.L418= | Silent (SNP) | VAF 34/140 reads (24%) | called by muse, mutect2, varscan2
- ATP1A4 | c.3015C>T p.F1005= | Silent (SNP) | VAF 17/183 reads (9%) | catalogued as rs200363709, COSV63624272; called by muse, mutect2
- ATP1B4 | c.304C>T p.L102= | Silent (SNP) | VAF 30/45 reads (67%) | called by muse, mutect2, varscan2
- BBS10 | c.927C>T p.L309= | Silent (SNP) | VAF 7/165 reads (4%) | called by muse, mutect2
- BEGAIN | c.981G>A p.L327= | Silent (SNP) | VAF 87/100 reads (87%) | catalogued as rs1373058421; called by muse, mutect2, varscan2
- BEST4 | c.396G>A p.A132= | Silent (SNP) | VAF 11/11 reads (100%) | catalogued as rs753302001; called by muse, mutect2, varscan2
- BMP10 | c.555C>G p.V185= | Silent (SNP) | VAF 38/420 reads (9%) | called by muse, mutect2
- BPTF | c.363C>T p.V121= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs1368063224; called by muse, mutect2
- BTBD7 | c.42G>A p.P14= | Silent (SNP) | VAF 54/58 reads (93%) | catalogued as rs1370005883; called by muse, mutect2, varscan2
- CACNA1B | c.2616G>A p.P872= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs944745345; called by muse, mutect2, varscan2
- CACNA1G | c.3555C>T p.R1185= | Silent (SNP) | VAF 42/100 reads (42%) | called by muse, mutect2, varscan2
- CCDC186 | c.2082C>T p.L694= | Silent (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- CCDC54 | c.420G>A p.V140= | Silent (SNP) | VAF 100/238 reads (42%) | called by muse, mutect2, varscan2
- CCDC71 | c.1164G>A p.Q388= | Silent (SNP) | VAF 54/194 reads (28%) | called by muse, mutect2, varscan2
- CCNYL1 | c.273C>T p.F91= (on ENST00000295414 / NM_001330218.2; = p.F21= on NM_152523.2) | Silent (SNP) | VAF 42/88 reads (48%) | called by muse, mutect2, varscan2
- CDK13 | c.624C>T p.R208= | Silent (SNP) | VAF 10/24 reads (42%) | called by mutect2, varscan2
- CEP89 | c.1647G>A p.K549= | Silent (SNP) | VAF 98/311 reads (32%) | called by muse, mutect2, varscan2
- CFAP54 | c.852C>G p.L284= | Silent (SNP) | VAF 4/88 reads (5%) | called by muse, mutect2
- CHAT | c.972C>T p.L324= | Silent (SNP) | VAF 25/196 reads (13%) | called by muse, mutect2, varscan2
- CHRM5 | c.231C>T p.L77= | Silent (SNP) | VAF 16/310 reads (5%) | called by muse, mutect2
- CHST12 | c.486G>A p.R162= | Silent (SNP) | VAF 184/389 reads (47%) | catalogued as rs372209247; called by muse, mutect2, varscan2
- CHST8 | c.861C>A p.I287= | Silent (SNP) | VAF 78/392 reads (20%) | called by muse, mutect2, varscan2
- CLDN7 | c.33C>T p.F11= | Silent (SNP) | VAF 24/130 reads (18%) | called by muse, mutect2, varscan2
- CLEC9A | c.216C>T p.L72= | Silent (SNP) | VAF 20/155 reads (13%) | called by muse, mutect2, varscan2
- CLN6 | c.333C>A p.S111= | Silent (SNP) | VAF 39/94 reads (41%) | called by muse, mutect2, varscan2
- CLPTM1 | c.516G>A p.K172= | Silent (SNP) | VAF 188/425 reads (44%) | called by muse, mutect2, varscan2
- CNNM2 | c.1050C>T p.I350= | Silent (SNP) | VAF 21/352 reads (6%) | called by muse, mutect2
- COL28A1 | c.3377G>A p.*1126= | Silent (SNP) | VAF 153/563 reads (27%) | catalogued as rs1451636140; called by muse, mutect2, varscan2
- COL4A1 | c.4899C>T p.L1633= | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as rs760487355; called by muse, mutect2, varscan2
- COL5A2 | c.357A>T p.G119= | Silent (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2, varscan2
- COPE | c.207C>G p.V69= | Silent (SNP) | VAF 114/404 reads (28%) | called by muse, mutect2, varscan2
- CUL9 | c.6312G>A p.R2104= | Silent (SNP) | VAF 63/678 reads (9%) | called by muse, mutect2
- CUX1 | c.2421G>A p.L807= | Silent (SNP) | VAF 31/95 reads (33%) | catalogued as COSV52908403; called by muse, mutect2, varscan2
- CUX1 | c.3618G>A p.K1206= | Silent (SNP) | VAF 5/95 reads (5%) | called by muse, mutect2
- CWC27 | c.1392G>A p.L464= | Silent (SNP) | VAF 19/54 reads (35%) | called by muse, mutect2, varscan2
- CX3CR1 | c.111C>T p.F37= | Silent (SNP) | VAF 46/206 reads (22%) | catalogued as rs1230064356; called by muse, mutect2, varscan2
- CYFIP1 | c.573C>T p.A191= | Silent (SNP) | VAF 34/72 reads (47%) | catalogued as rs376286542; called by muse, mutect2, varscan2
- CYP2C8 | c.1140C>G p.L380= | Silent (SNP) | VAF 28/123 reads (23%) | catalogued as rs375186872; called by muse, mutect2, varscan2
- CYP4A11 | c.1302C>T p.F434= | Silent (SNP) | VAF 15/216 reads (7%) | called by muse, mutect2
- DBF4 | c.1689C>T p.F563= | Silent (SNP) | VAF 36/155 reads (23%) | catalogued as rs1485298794; called by muse, mutect2, varscan2
- DCBLD1 | c.2118C>T p.L706= | Silent (SNP) | VAF 14/276 reads (5%) | called by muse, mutect2
- DDX54 | c.2490G>A p.L830= | Silent (SNP) | VAF 14/119 reads (12%) | called by muse, mutect2, varscan2
- DENND4B | c.207G>A p.Q69= | Silent (SNP) | VAF 159/342 reads (46%) | called by muse, mutect2, varscan2
- DFFB | c.651C>G p.L217= | Silent (SNP) | VAF 5/90 reads (6%) | called by muse, mutect2
- DICER1 | c.210G>A p.K70= | Silent (SNP) | VAF 18/183 reads (10%) | called by muse, mutect2, varscan2
- DIDO1 | c.1257C>T p.L419= | Silent (SNP) | VAF 33/126 reads (26%) | called by muse, mutect2, varscan2
- DLG4 | c.1884C>T p.L628= (on ENST00000399506 / NM_001321075.3; = p.L671= on NM_001365.4) | Silent (SNP) | VAF 33/86 reads (38%) | catalogued as rs574653579, COSV57237052; called by muse, mutect2, varscan2
- DNAH7 | c.3381C>T p.L1127= | Silent (SNP) | VAF 12/314 reads (4%) | catalogued as rs1360565564; called by muse, mutect2
- DNAI1 | c.2099G>A p.*700= | Silent (SNP) | VAF 152/310 reads (49%) | called by muse, mutect2, varscan2
- DNAJC11 | c.90G>T p.L30= | Silent (SNP) | VAF 24/28 reads (86%) | catalogued as rs1322144444, COSV53788345; called by muse, mutect2, varscan2
- DOCK10 | c.6354C>T p.L2118= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as COSV51382278; called by muse, mutect2, varscan2
- DPH7 | c.1358G>A p.*453= | Silent (SNP) | VAF 20/132 reads (15%) | called by muse, mutect2, varscan2
- DSG3 | c.1029G>A p.V343= | Silent (SNP) | VAF 116/258 reads (45%) | catalogued as COSV57128094; called by muse, mutect2, varscan2
- EFHC2 | c.786C>T p.I262= | Silent (SNP) | VAF 9/72 reads (13%) | called by muse, mutect2, varscan2
- EGFL8 | c.520C>T p.L174= | Silent (SNP) | VAF 12/169 reads (7%) | called by muse, mutect2
- EIF4G1 | c.2640G>C p.L880= (on ENST00000346169 / NM_198241.3; = p.L685= on NM_004953.5) | Silent (SNP) | VAF 25/95 reads (26%) | called by muse, mutect2, varscan2
- ESCO1 | c.300G>A p.K100= | Silent (SNP) | VAF 57/105 reads (54%) | catalogued as COSV52520463; called by muse, mutect2, varscan2
- F11 | c.1860G>A p.E620= | Silent (SNP) | VAF 7/139 reads (5%) | catalogued as COSV99250693; called by muse, mutect2
- FAM120A | c.1803C>T p.L601= | Silent (SNP) | VAF 18/260 reads (7%) | called by muse, mutect2
- FAM216B | c.414G>A p.R138= | Silent (SNP) | VAF 20/77 reads (26%) | called by muse, mutect2, varscan2
- FAM71E1 | c.711C>T p.L237= (on ENST00000600100 / NM_001308429.2; = p.L221= on NM_138411.3) | Silent (SNP) | VAF 109/249 reads (44%) | called by muse, mutect2, varscan2
- FAR2 | c.1182C>T p.F394= | Silent (SNP) | VAF 54/196 reads (28%) | catalogued as COSV51725592; called by muse, mutect2, varscan2
- FGF3 | c.519G>A p.Q173= | Silent (SNP) | VAF 10/141 reads (7%) | catalogued as COSV61925367; called by muse, mutect2
- FGFRL1 | c.372G>A p.K124= | Silent (SNP) | VAF 14/48 reads (29%) | called by muse, mutect2, varscan2
- FGG | c.804C>T p.I268= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as rs554574114; called by muse, mutect2, varscan2
- FILIP1L | c.1384C>T p.L462= (on ENST00000354552 / NM_182909.3; = p.L222= on NM_014890.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 73/174 reads (42%) | called by muse, mutect2, varscan2
- FLI1 | c.573C>T p.L191= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as rs1408294515, COSV55644986; called by muse, mutect2
- FMO2 | c.909G>A p.V303= | Silent (SNP) | VAF 22/103 reads (21%) | catalogued as COSV52948393; called by muse, mutect2, varscan2
- FMR1 | c.1122G>A p.Q374= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV99503277; called by muse, mutect2, varscan2
- FOCAD | c.1377C>T p.L459= | Silent (SNP) | VAF 8/240 reads (3%) | called by muse, mutect2
- FOXM1 | c.1482C>T p.F494= | Silent (SNP) | VAF 111/251 reads (44%) | called by muse, mutect2, varscan2
- FSIP2 | c.4995G>A p.L1665= | Silent (SNP) | VAF 7/143 reads (5%) | called by muse, mutect2
- GALP | c.30C>T p.L10= | Silent (SNP) | VAF 12/196 reads (6%) | called by muse, mutect2
- GDPD1 | c.597C>G p.L199= | Silent (SNP) | VAF 14/428 reads (3%) | called by muse, mutect2
- GLRX3 | c.399C>T p.L133= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV100488025; called by muse, mutect2, varscan2
- GNAO1 | c.630G>A p.K210= | Silent (SNP) | VAF 110/115 reads (96%) | catalogued as rs778453425, COSV99341049; called by muse, mutect2, varscan2
- GNAT3 | c.922C>T p.L308= | Silent (SNP) | VAF 27/161 reads (17%) | called by muse, mutect2, varscan2
- GPR34 | c.819C>T p.I273= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV59363373; called by muse, mutect2
- GREB1 | c.312C>T p.V104= | Silent (SNP) | VAF 52/157 reads (33%) | called by muse, mutect2, varscan2
- GRM5 | c.3507C>T p.F1169= (on ENST00000305447 / NM_001143831.2; = p.F1137= on NM_000842.4) | Silent (SNP) | VAF 116/175 reads (66%) | called by muse, mutect2, varscan2
- GXYLT1 | c.963G>A p.L321= | Silent (SNP) | VAF 24/108 reads (22%) | catalogued as COSV99788360; called by muse, mutect2, varscan2
- HDGFL2 | c.219G>A p.K73= | Silent (SNP) | VAF 64/137 reads (47%) | catalogued as COSV56685139; called by muse, mutect2, varscan2
- HIRA | c.1308G>A p.E436= | Silent (SNP) | VAF 23/97 reads (24%) | called by muse, mutect2, varscan2
- HK2 | c.1329C>T p.L443= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as COSV51875380, COSV51880387; called by muse, mutect2, varscan2
- HMCN1 | c.6714G>A p.L2238= | Silent (SNP) | VAF 30/149 reads (20%) | called by muse, mutect2, varscan2
- HSPA13 | c.1365C>T p.V455= | Silent (SNP) | VAF 55/329 reads (17%) | called by muse, mutect2, varscan2
- IGSF22 | c.1296G>A p.E432= | Silent (SNP) | VAF 23/170 reads (14%) | catalogued as COSV60033507; called by muse, mutect2, varscan2
- IHO1 | c.771G>C p.L257= | Silent (SNP) | VAF 45/144 reads (31%) | called by muse, mutect2, varscan2
- IPO5 | c.516C>T p.V172= | Silent (SNP) | VAF 63/150 reads (42%) | called by muse, mutect2, varscan2
- IQCN | c.1044G>A p.V348= | Silent (SNP) | VAF 39/208 reads (19%) | called by muse, mutect2, varscan2
- IQSEC2 | c.2643C>T p.I881= (on ENST00000642864 / NM_001111125.3; = p.I676= on NM_015075.2) | Silent (SNP) | VAF 54/59 reads (92%) | called by muse, mutect2, varscan2
- ISCA1 | c.75C>T p.L25= | Silent (SNP) | VAF 54/66 reads (82%) | catalogued as COSV58181309; called by muse, mutect2, varscan2
- ITPR3 | c.5538C>T p.P1846= | Silent (SNP) | VAF 59/167 reads (35%) | catalogued as rs1262772682; called by muse, mutect2, varscan2
- JARID2 | c.30C>T p.I10= | Silent (SNP) | VAF 56/317 reads (18%) | catalogued as rs1270076494; called by muse, mutect2, varscan2
- KALRN | c.5781G>A p.L1927= (on ENST00000360013 / NM_001024660.4; = p.L230= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 60/184 reads (33%) | catalogued as COSV52254598; called by muse, mutect2, varscan2
- KAT2A | c.1137C>T p.F379= | Silent (SNP) | VAF 10/273 reads (4%) | called by muse, mutect2
- KCNA5 | c.927C>T p.G309= | Silent (SNP) | VAF 102/191 reads (53%) | catalogued as rs749646022; called by muse, mutect2, varscan2
- KCND3 | c.864G>A p.T288= | Silent (SNP) | VAF 76/187 reads (41%) | catalogued as rs769635941, COSV56188117; called by muse, mutect2, varscan2
- KCNH3 | c.339G>C p.V113= | Silent (SNP) | VAF 29/82 reads (35%) | called by muse, mutect2, varscan2
- KCNQ2 | c.426C>T p.F142= | Silent (SNP) | VAF 21/387 reads (5%) | catalogued as rs780770793, COSV60438733; ClinVar: likely benign; called by muse, mutect2
- KCTD3 | c.330C>T p.L110= | Silent (SNP) | VAF 8/204 reads (4%) | called by muse, mutect2
- KIF26B | c.105C>T p.F35= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as rs945049728; called by muse, mutect2, varscan2
- KLHL42 | c.1410C>G p.L470= | Silent (SNP) | VAF 6/162 reads (4%) | called by muse, mutect2
- KRI1 | c.633G>A p.E211= | Silent (SNP) | VAF 124/321 reads (39%) | catalogued as rs1470730653, COSV57264253; called by muse, mutect2, varscan2
- LAMA3 | c.7939C>T p.L2647= (on ENST00000313654 / NM_198129.4; = p.L1038= on NM_000227.6) | Silent (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2, varscan2
- LARGE2 | c.156C>T p.L52= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs1391770060; called by muse, varscan2
- LARP6 | c.735G>A p.R245= | Silent (SNP) | VAF 22/126 reads (17%) | catalogued as COSV54579784; called by muse, mutect2, varscan2
- LBH | c.261C>T p.V87= | Silent (SNP) | VAF 59/141 reads (42%) | called by muse, mutect2, varscan2
- LILRA1 | c.153G>T p.G51= | Silent (SNP) | VAF 62/145 reads (43%) | catalogued as COSV52177913; called by muse, varscan2
- LRP1 | c.12852C>A p.V4284= | Silent (SNP) | VAF 11/184 reads (6%) | called by muse, mutect2
- LRRC55 | c.576G>A p.Q192= | Silent (SNP) | VAF 9/207 reads (4%) | called by muse, mutect2
- LRRC75A | c.72C>G p.R24= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- LRRC9 | c.2874C>T p.L958= | Silent (SNP) | VAF 29/31 reads (94%) | called by muse, mutect2, varscan2
- MAGI3 | c.2475C>T p.F825= | Silent (SNP) | VAF 6/83 reads (7%) | called by muse, mutect2
- MBD6 | c.1587G>A p.L529= | Silent (SNP) | VAF 30/170 reads (18%) | called by muse, mutect2, varscan2
- MCF2L | c.1815G>A p.R605= (on ENST00000375608; = p.R573= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 43/96 reads (45%) | called by muse, mutect2, varscan2
- MEPE | c.339G>A p.R113= | Silent (SNP) | VAF 144/489 reads (29%) | called by muse, mutect2, varscan2
- MFSD8 | c.39C>T p.L13= | Silent (SNP) | VAF 17/297 reads (6%) | catalogued as rs1456015788, COSV56553321; called by muse, mutect2
- MIGA2 | c.84G>A p.T28= | Silent (SNP) | VAF 133/228 reads (58%) | catalogued as rs146566671; called by muse, mutect2, varscan2
- MMD | c.12G>A p.K4= | Silent (SNP) | VAF 30/178 reads (17%) | catalogued as COSV50434205; called by muse, mutect2, varscan2
- MMD2 | c.27C>T p.F9= | Silent (SNP) | VAF 26/117 reads (22%) | catalogued as rs1174385121, COSV68661201; called by muse, mutect2, varscan2
- MMP11 | c.450G>A p.E150= | Silent (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- MRC1 | c.3808C>T p.L1270= | Silent (SNP) | VAF 25/144 reads (17%) | called by muse, mutect2, varscan2
- MTTP | c.2184G>A p.V728= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as COSV55508718; called by muse, mutect2
- MYO1B | c.1182C>T p.F394= | Silent (SNP) | VAF 9/131 reads (7%) | catalogued as rs1437595675, COSV58430850, COSV58434427, COSV58437963; called by muse, mutect2
- NAPB | c.39G>A p.L13= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV65464808; called by muse, mutect2, varscan2
- NDST3 | c.903G>A p.L301= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as rs376843065; called by muse, mutect2
- NDUFB8 | c.24C>T p.V8= | Silent (SNP) | VAF 154/359 reads (43%) | catalogued as rs1323742319; called by muse, mutect2, varscan2
- NEBL | c.1468C>T p.L490= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as rs765843006; called by muse, mutect2, varscan2
- NFKB2 | c.240C>A p.V80= | Silent (SNP) | VAF 100/216 reads (46%) | called by muse, mutect2, varscan2
- NOP14 | c.2556G>A p.R852= | Silent (SNP) | VAF 45/221 reads (20%) | catalogued as rs775594224; called by muse, mutect2, varscan2
- NOTCH3 | c.372C>T p.L124= | Silent (SNP) | VAF 7/166 reads (4%) | called by muse, mutect2
- NPR1 | c.675C>T p.L225= | Silent (SNP) | VAF 7/143 reads (5%) | called by muse, mutect2
- NPR1 | c.1092G>A p.V364= | Silent (SNP) | VAF 120/283 reads (42%) | called by muse, mutect2, varscan2
- NUAK1 | c.1533G>A p.R511= | Silent (SNP) | VAF 47/246 reads (19%) | catalogued as rs150517304; called by muse, mutect2, varscan2
- NUP210L | c.3876C>T p.L1292= | Silent (SNP) | VAF 14/247 reads (6%) | called by muse, mutect2
- NUP98 | c.4494C>G p.L1498= (on ENST00000359171 / NM_001365126.1; = p.L1481= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 23/60 reads (38%) | called by muse, mutect2, varscan2
- OR2J1 | c.24T>C p.S8= | Silent (SNP) | VAF 63/129 reads (49%) | called by muse, mutect2, varscan2
- OR2M7 | c.771C>T p.F257= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as COSV100522583; called by muse, mutect2, varscan2
- OR4K2 | c.867G>A p.L289= | Silent (SNP) | VAF 29/97 reads (30%) | catalogued as COSV53848379; called by muse, mutect2, varscan2
- OR51Q1 | c.210G>A p.L70= | Silent (SNP) | VAF 62/411 reads (15%) | catalogued as rs747607216; called by muse, mutect2, varscan2
- OR5K2 | c.36T>C p.F12= | Silent (SNP) | VAF 60/245 reads (24%) | called by muse, mutect2, varscan2
- OTOP3 | c.198G>A p.Q66= | Silent (SNP) | VAF 17/127 reads (13%) | catalogued as rs1407940898; called by muse, mutect2, varscan2
- OXGR1 | c.855C>T p.I285= | Silent (SNP) | VAF 10/209 reads (5%) | catalogued as rs1240445214, COSV53657345; called by muse, mutect2
- P4HB | c.210G>A p.L70= | Silent (SNP) | VAF 69/136 reads (51%) | catalogued as COSV100515941, COSV58940157; called by muse, mutect2, varscan2
- PACS2 | c.1410G>A p.R470= | Silent (SNP) | VAF 12/121 reads (10%) | called by muse, mutect2
- PAQR9 | c.303C>T p.F101= | Silent (SNP) | VAF 207/475 reads (44%) | catalogued as COSV61417905; called by muse, mutect2, varscan2
- PARD3 | c.1425C>T p.I475= | Silent (SNP) | VAF 34/56 reads (61%) | catalogued as rs1415289364; called by muse, mutect2, varscan2
- PAX1 | c.876C>T p.V292= | Silent (SNP) | VAF 144/344 reads (42%) | catalogued as COSV68273370; called by muse, mutect2, varscan2
- PCLO | c.5337G>A p.L1779= | Silent (SNP) | VAF 25/160 reads (16%) | catalogued as COSV100427144, COSV61636666; called by muse, mutect2, varscan2
- PDE1C | c.1350G>C p.V450= | Silent (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- PIK3R3 | c.1273C>T p.L425= | Silent (SNP) | VAF 55/60 reads (92%) | catalogued as COSV53103938; called by muse, mutect2, varscan2
- PLCD3 | c.729C>T p.I243= | Silent (SNP) | VAF 107/337 reads (32%) | catalogued as rs567798651, COSV59561623; called by muse, mutect2, varscan2
- PLEKHS1 | c.369C>T p.F123= (on ENST00000369310 / NM_182601.1; = p.F129= on NM_024889.5) | Silent (SNP) | VAF 79/182 reads (43%) | catalogued as COSV63055831; called by muse, mutect2, varscan2
- PMVK | c.75G>A p.V25= | Silent (SNP) | VAF 123/243 reads (51%) | called by muse, mutect2, varscan2
894 further variants in this file (0 protein-altering or splice-affecting, 90 silent, 804 other) are not listed here.
